MMRF case MMRF_1677 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/46cbe0e8-a97f-43ae-bab7-ddb4f760756c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.1 years (18,649 days); ISS stage: II; Days to last known disease status: 1,135 days (3.1 years); Days to last follow up: 1,135 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 26 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 38 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 218 days; Days to treatment end: 574 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 218 days.
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: Liposomal Doxorubicin Regimen; Days to treatment start: 300 days; Days to treatment end: 300 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 300 days; Days to treatment end: 300 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26 (ECOG 0): M Protein 5.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.064 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15 mg/dL; Immunoglobulin G 84.1 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 3.74 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 10.9 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.08 mg/dL.
- Day 69 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.051 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.33 mg/dL; Immunoglobulin G 42.4 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 1.05 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.03 mmol/L; Albumin 37 g/L; Total Protein 9.2 g/dL; Glucose 5.89 mmol/L.
- Day 142 (ECOG 0): M Protein 2.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.055 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.83 mg/dL; Immunoglobulin G 27.8 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.8 g/dL; Glucose 5.5 mmol/L.
- Day 182: M Protein 2.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.042 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7 mg/dL; Immunoglobulin G 33.1 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 8.4 g/dL; Glucose 5.61 mmol/L.
- Day 273 (ECOG 0): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.054 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 393 (ECOG 0): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.098 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.47 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 6.16 mmol/L.
- Day 476 (ECOG 0): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.82 µg/mL; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.05 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 6.6 mmol/L.
- Day 574 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 3.67 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.06 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 637 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 4.22 g/L; Creatinine 71.6 µmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L.
- Day 756 (ECOG 0): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.692 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6.33 mmol/L.
- Day 932 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.965 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.14 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.07 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 7.98 mmol/L.
- Day 1,135 (ECOG 0): M Protein 0.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.832 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.06 mg/dL; Immunoglobulin G 8.42 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -26: Weight: 98 kg; Height: 176 cm.

Biospecimens (2 samples)
- Sample MMRF_1677_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_1677_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
